Somatic mutation profile of tumor specimen TCGA-ER-A3ET-06A (aliquot TCGA-ER-A3ET-06A-11D-A20D-08) from TCGA case TCGA-ER-A3ET, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.9 years (25,893 days).
Specimen TCGA-ER-A3ET-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0dbb582-d46f-4933-8eec-b0e7e253200e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A3ET-10A (Blood Derived Normal), aliquot TCGA-ER-A3ET-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf4434e5-f531-4f2e-a367-365930d9b578

The open-access MAF lists 99 somatic variants for this specimen: 81 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 16, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1, RNA 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GNA11 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV50018251, COSV99312939; called by muse, mutect2, varscan2
- KCNH2 | c.1838C>T p.T613M | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199473524, CM990761, BM1347533, COSV51233401; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 38/44 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ACKR1 | c.131A>T p.N44I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.452); catalogued as COSV63674814; called by muse, mutect2, varscan2
- ADGRB3 | c.875C>A p.S292Y | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV65422732; called by muse, mutect2, varscan2
- ADH7 | c.218A>T p.K73M | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV52920112, COSV52923475; called by muse, mutect2, varscan2
- ALK | c.560T>A p.I187N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV66591734; called by muse, mutect2, varscan2
- ANK1 | c.5210C>T p.T1737I | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.096); catalogued as COSV55897580; called by muse, mutect2, varscan2
- ATOH1 | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV60038874; called by muse, mutect2, varscan2
- ATRX | c.3802G>T p.E1268* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV64879462; called by muse, mutect2, varscan2
- BABAM2 | c.671G>C p.R224P | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV59624470, COSV59630226, COSV59633919; called by muse, mutect2, varscan2
- BBX | c.2815G>A p.A939T (on ENST00000325805 / NM_001142568.3; = p.A909T on NM_020235.7) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1188606110, COSV57883065; called by muse, mutect2, varscan2
- CDK17 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs147593071; called by muse, mutect2, varscan2
- CEP57 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs774404375, COSV57687405; called by muse, varscan2
- CMYA5 | c.7888G>A p.E2630K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.985); catalogued as COSV71409962; called by muse, mutect2, varscan2
- CNTN5 | c.57G>A p.E19= | Splice Region (SNP) | VAF 12/67 reads (18%) | catalogued as rs768027790, COSV54361981; called by muse, mutect2
- CROT | c.1167G>T p.R389S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV58976236, COSV58977137; called by muse, mutect2, varscan2
- CSMD3 | c.4685G>C p.G1562A (on ENST00000297405 / NM_001363185.1; = p.G1458A on NM_052900.3) | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52165005, COSV52335107; called by muse, mutect2, varscan2
- CXorf66 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.274); catalogued as COSV65169861; called by muse, mutect2, varscan2
- DAB1 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV100976715; called by muse, mutect2, varscan2
- DCAF6 | c.952G>C p.D318H | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV56586119; called by muse, mutect2, varscan2
- DCAF8L1 | c.299G>T p.R100M | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.157); catalogued as COSV71595560; called by muse, mutect2, varscan2
- DEPDC4 | c.120G>C p.R40S | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV54554534; called by muse, mutect2, varscan2
- DIAPH2 | c.2504A>T p.E835V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV61294585; called by muse, mutect2, varscan2
- DRD5 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV58578068; called by muse, mutect2, varscan2
- EIF4G2 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 122/196 reads (62%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.932); catalogued as COSV101151167; called by muse, mutect2, varscan2
- ELK3 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1364859001, COSV57388507; called by muse, mutect2, varscan2
- EPHB1 | c.2919G>T p.R973S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs368683804, COSV67672863; called by muse, mutect2, varscan2
- GABRB2 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1046312221, COSV50954718; called by muse, mutect2, varscan2
- GNAO1 | c.966C>A p.H322Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52621270; called by muse, mutect2, varscan2
- HHLA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771206254, COSV63315976; called by muse, mutect2, varscan2
- HSD3B1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV52490654; called by muse, mutect2, varscan2
- HSPA1L | c.1858C>G p.P620A | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as COSV65151354; called by muse, mutect2, varscan2
- HTR3B | c.860A>C p.N287T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV52748035; called by muse, mutect2
- IGKV1-16 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs781184992; called by muse, varscan2
- KCNT2 | c.2982C>G p.S994R | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV54112015; called by muse, mutect2, varscan2
- KLC2 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs773382725, COSV57584583; called by muse, mutect2, varscan2
- KMT2A | c.7265C>T p.S2422F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as COSV63293213; called by muse, mutect2, varscan2
- KRT16 | c.1200C>G p.Y400* | Nonsense Mutation (SNP) | VAF 58/183 reads (32%) | catalogued as COSV56969972; called by muse, mutect2, varscan2
- LRRIQ4 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV61620390; called by muse, mutect2, varscan2
- MAN2A1 | c.3146T>G p.V1049G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54859339; called by muse, mutect2, varscan2
- MOV10L1 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs756494636, COSV53180612; called by muse, mutect2, varscan2
- MTAP | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs1440590492, COSV66478211, COSV66478653; called by muse, mutect2, varscan2
- MYO16 | c.2900G>T p.G967V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV51810449, COSV51821086; called by muse, mutect2, varscan2
- NISCH | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV61902621; called by muse, mutect2, varscan2
- OR1A2 | c.557A>T p.K186M | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV67936875; called by muse, mutect2, varscan2
- OR2W1 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.577); catalogued as rs534275831, COSV65851999; called by muse, mutect2, varscan2
- OR51M1 | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1282408883, COSV60785616; called by muse, mutect2, varscan2
- OTP | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV60570091; called by muse, mutect2, varscan2
- PAIP1 | c.272C>G p.T91R | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs562316321, COSV59088001; called by muse, mutect2, varscan2
- PLCB4 | c.2778+1G>T p.X926_splice | Splice Site (SNP) | VAF 9/94 reads (10%) | catalogued as COSV53820367; called by muse, mutect2, varscan2
- PLXNA3 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.969); catalogued as COSV63755952; called by muse, mutect2, varscan2
- PREX2 | c.4376C>G p.P1459R | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV55802193; called by muse, mutect2, varscan2
- PWP1 | c.999T>A p.D333E | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV69833540; called by muse, mutect2, varscan2
- RABGAP1L | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV52332143; called by muse, mutect2, varscan2
- RIMS3 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65505542; called by muse, mutect2, varscan2
- RPS6KB1 | c.1520A>G p.K507R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.107); catalogued as rs770364465, COSV56679919; called by muse, mutect2, varscan2
- RYR2 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV63718090; called by muse, mutect2, varscan2
- SI | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs201105530, COSV52281341, COSV52303550; called by muse, mutect2, varscan2
- SIGLEC8 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58473766, COSV58476119; called by muse, mutect2
- SLC1A3 | c.594C>G p.S198R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54320905; called by muse, mutect2
- SLC1A3 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229578292, COSV54314880, COSV99468288; called by muse, mutect2, varscan2
- SLC22A23 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66679773; called by muse, mutect2
- SND1 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.177); catalogued as COSV61250131; called by muse, mutect2, varscan2
- SPIDR | c.2340A>T p.Q780H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV52392147; called by muse, mutect2, varscan2
- TEKT5 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1419137348, COSV51588605; called by muse, mutect2, varscan2
- THBS4 | c.1954C>A p.L652M | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63471145; called by muse, mutect2
- TIMD4 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV50854909; called by muse, mutect2, varscan2
- TRRAP | c.4496G>C p.R1499T | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.599); catalogued as COSV62855413; called by muse, mutect2, varscan2
- TRRAP | c.6385C>T p.L2129F (on ENST00000359863 / NM_001244580.1; = p.L2111F on NM_003496.3) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1405083768, COSV100723111; called by muse, mutect2, varscan2
- TRRAP | c.6472C>T p.Q2158* (on ENST00000359863 / NM_001244580.1; = p.Q2140* on NM_003496.3) | Nonsense Mutation (SNP) | VAF 34/198 reads (17%) | catalogued as COSV62855420; called by muse, varscan2
- TXNRD2 | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57636004; called by muse, mutect2
- USH1C | c.522-1G>C p.X174_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV50039313; called by mutect2, varscan2
- WAS | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1260793617, COSV64997814; called by muse, mutect2
- WIPF1 | c.249_263del p.G86_G90del | In Frame Del (DEL) | VAF 38/103 reads (37%) | catalogued as rs1559148619; called by mutect2, varscan2
- ZNF208 | c.2330A>G p.Y777C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV68113416; called by muse, mutect2, varscan2
- ZNF214 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as rs750884983, COSV53483899; called by muse, mutect2, varscan2
- CD247 | c.219+1del p.X73_splice | Splice Site (DEL) | VAF 25/188 reads (13%) | called by mutect2, pindel, varscan2
- MEPCE | c.731_753del p.C244Sfs*13 | Frame Shift Del (DEL) | VAF 42/444 reads (9%) | called by mutect2, pindel
- OR5D13 | c.648_655del p.L217Ifs*46 | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | called by mutect2, pindel, varscan2
- CCDC180 | c.3606G>A p.G1202= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs767087302, COSV63835994; called by muse, mutect2, varscan2
- CLEC18B | c.585C>A p.I195= | Silent (SNP) | VAF 18/268 reads (7%) | catalogued as COSV60578997, COSV60579076; called by muse, mutect2
- EDDM3A | c.384C>T p.G128= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs759499952, COSV58795573; called by muse, mutect2, varscan2
- FANK1 | c.495T>C p.S165= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV64157236; called by muse, mutect2, varscan2
- GRB14 | c.825G>A p.R275= | Silent (SNP) | VAF 56/80 reads (70%) | catalogued as rs750803021, COSV55742978, COSV55744099; called by muse, mutect2, varscan2
- HMGCS2 | c.1281G>A p.Q427= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV65568340, COSV65569522; called by muse, mutect2
- ITGB5 | c.1905C>T p.C635= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs767344661, COSV56153520; called by muse, mutect2, varscan2
- LRP1B | c.2622C>T p.S874= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs775728525, COSV63341565; called by muse, mutect2, varscan2
- MASP1 | c.591C>T p.I197= | Silent (SNP) | VAF 28/120 reads (23%) | catalogued as COSV51464285; called by muse, varscan2
- PDSS1 | c.537C>T p.H179= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs773495425, COSV66058782; ClinVar: likely benign; called by muse, mutect2, varscan2
- POU6F2 | c.1443G>A p.L481= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1168530637, COSV68872736, COSV68881209; called by muse, mutect2, varscan2
- PTCD2 | c.43C>A p.R15= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV54651361, COSV54654034, COSV99781895; called by muse, mutect2, varscan2
- TEK | c.2460C>T p.D820= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV66235404; called by muse, mutect2, varscan2
- TGM4 | c.1158C>T p.F386= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV56096959; called by muse, mutect2, varscan2
- TRRAP | c.6384C>T p.N2128= (on ENST00000359863 / NM_001244580.1; = p.N2110= on NM_003496.3) | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV100723107; called by muse, mutect2, varscan2
- ZAN | c.4149T>G p.L1383= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV61817699; called by muse, mutect2, varscan2
- MSLNL | c.37+1323G>A | Intron (SNP) | VAF 10/17 reads (59%) | catalogued as COSV50102749; called by muse, mutect2, varscan2
- RPL23AP42 | n.404A>C | RNA (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
